Surgical pathology report (de-identified scan), TCGA case TCGA-DZ-6133, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DZ-6133-01A (Primary Tumor).

[REDACTED]

[REDACTED] Surgical Pathology

[REDACTED] TCGA-DZ-6133

TISSUE DESCRIPTION:

C2

Right kidney (4.6 x 3.8 x 3.2 cm), tissue from right chest (5.0 x 3.2 x 1.5 cm with skin ellipse--4.0 x 1.1 cm), and new superior right chest margin (3.9 x 2.0 x 1.1 cm)

DIAGNOSIS:

Kidney, right, partial nephrectomy: Grade 2 (of 4) renal cell

carcinoma, papillary type, forms a 3.1 x 3.0 x 2.8 cm mass. The

tumor is confined to the kidney. Coagulative tumor necrosis is not present. Sarcomatoid differentiation is absent. The surgical margins are negative.

Skin right chest, excisional biopsy: Infiltrating grade 3 (of 4)

carcinoma consistent with breast primary is identified within a

previous biopsy site and scar tissue over an area measuring 1.0 cm

in greatest dimension. The tumor involves the dermis and subcutaneous tissue. Margins of excision following re-excision of

the superior margin are negative for tumor.

Source: NCI Genomic Data Commons file 9dd6e151-2cf4-4189-902a-5197c5d20e41 (TCGA-DZ-6133.553E7312-3CF1-4B69-BC01-C811557670C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).